Gene-level copy-number profile of tumor specimen TCGA-D1-A2G7-01A from TCGA case TCGA-D1-A2G7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.5 years (23,913 days).
Specimen TCGA-D1-A2G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.ca99ea64-d659-46e3-acf0-aaad68d89aaf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A2G7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd5a8555-a1c5-4750-9e6e-16faa988735b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,009; copy number 2: 45,834; copy number 3: 4,830; copy number 4: 914; copy number 5: 102; copy number 6: 11; copy number 8: 1; copy number 9: 11; copy number 15: 50; copy number 20: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A2G7-01A-21D-A17U-01): tumor purity 0.71, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,938,104–41,043,890, 6 genes, copy number 9 (within-gene range 4–9): AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1.
- chr1:68,679,202–70,151,945, 9 genes, copy number 5 (within-gene range 3–5): AL033530.1, AL691520.1, LINC01707, LINC02791, LINC01758, AL359894.1, LRRC7, SGO1P1, AL117353.1.
- chr1:147,019,656–148,255,012, 43 genes, copy number 8–20 (within-gene range 3–20): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1.
- chr1:149,782,671–152,042,774, 134 genes, copy number 5–15 (within-gene range 2–15) (broad region; genes not listed).
- chr3:62,221,249–63,616,924, 14 genes, copy number 5: PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134.
- chr3:170,222,424–170,454,733, 6 genes, copy number 6: PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 6: MIR6828.
- chr4:152,927,446–153,091,563, 4 genes, copy number 6: FAM192BP, AC093599.2, FHDC1, AC093599.1.

Autosomal genes at a single copy (total copy number 1): 8,009. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
